TARGET case TARGET-15-PAREAT — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3bb9362-30a9-45d1-8672-1026f08d3197

Demographics
Sex at birth: male; Age at index: 6 years; Vital status: Dead; Days to death: 74 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 6.6 years (2,399 days); Year of diagnosis: 2007; Days to last follow up: 74 days.

Follow-up (1 entry)
- Days to follow up: 74 days; First event: Relapse; Year of follow up: 2007.

Biospecimens (3 samples)
- Samples TARGET-15-PAREAT-09A, TARGET-15-PAREAT-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-PAREAT-15A: Sample type: Fibroblasts from Bone Marrow Normal; Tissue type: Normal; Specimen type: Fibroblasts from Bone Marrow.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 74
- Protocol: COG
- Karyotype: 46, XY, t(10;110 (p12;q21) [10] / 46, XY [11]
- WHO ALAL Classification: T/M
- WHO Dx: AML
- WHO RL1: T/M
